Gene-level copy-number profile of tumor specimen ALCH-B2LK-TTP1-A from ALCHEMIST case ALCH-B2LK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 70.9 years (25,900 days).
Specimen ALCH-B2LK-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 395d5b66-2826-43d1-851a-68d7ebc34c56.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2LK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/2e8c48fe-c8af-40ba-a6a3-8f093327d0d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13; copy number 2: 49,846; copy number 3: 8,349; copy number 4: 74; copy number 5: 88; copy number 6: 19.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 107 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:67,512,034–67,515,393, 1 gene, copy number 5: BX664730.1.
- chr11:1,074,875–1,685,629, 19 genes, copy number 5: MUC2, MUC5AC, MUC5B, MUC5B-AS1, MIR6744, TOLLIP, TOLLIP-AS1, BRSK2, MOB2, DUSP8, KRTAP5-AS1, KRTAP5-1, KRTAP5-2, KRTAP5-3, KRTAP5-4, KRTAP5-5, AP006285.1, FAM99A, FAM99B.
- chr11:2,268,495–2,423,045, 11 genes, copy number 6: ASCL2, C11orf21, TSPAN32, RNU6-878P, CD81-AS1, RPL26P30, Y_RNA, CD81, TSSC4, AC124057.1, TRPM5.
- chr11:3,084,393–3,085,443, 1 gene, copy number 5: AC108448.2.
- chr11:6,606,294–6,658,396, 8 genes, copy number 6 (within-gene range 2–6): TAF10, AC091564.3, AC091564.7, TPP1, AC091564.6, DCHS1, AC091564.4, AC091564.5.
- chr14:35,157,904–38,371,338, 66 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:43,461,960–43,479,534, 1 gene, copy number 5 (within-gene range 3–5): LINC00313.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
